RC case RC-B65M — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Lymph nodes. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e06fd138-03f7-4688-a884-240e9ecfe112

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1975; Vital status: Dead; Days to death: 1,532 days (4.2 years); Year of death: 2020; Country of birth: Dominican Republic.

Diagnoses (3)
1. Adult T-cell leukemia/lymphoma (HTLV-1 positive) (includes all variants) (the primary disease): ICD-O-3 morphology code: 9827/3; ICD-10 code: C84; Tissue or organ of origin: Lymph node, NOS; Site of resection or biopsy: Blood; Classification of tumor: primary; Age at diagnosis: 40.4 years (14,739 days); Year of diagnosis: 2016; Method of diagnosis: Core Biopsy; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): High-Intermediate Risk; Sites of involvement: Lymph Node, Cervical / Lymph Node, Hilar / Lymph Node, Inguinal / Lymph Node, Mesenteric / Bone marrow / Lung, NOS / Peripheral blood / Skin / Spleen.
   Pathology details: Bone marrow malignant cells: Yes; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Etoposide + Prednisone + Vincristine; Initial disease status: Initial Diagnosis; Regimen or line of therapy: EPOCH; Days to treatment start: 45 days; Days to treatment end: 112 days; Number of cycles: 3; Treatment outcome: Progressive Disease; Reason treatment ended: Disease Progression; Timepoint category: First Treatment; Treatment effect indicator: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Methotrexate; Initial disease status: Initial Diagnosis; Days to treatment start: 45 days; Days to treatment end: 112 days; Number of cycles: 3; Treatment outcome: Progressive Disease; Reason treatment ended: Disease Progression; Timepoint category: First Treatment; Treatment effect indicator: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cytarabine + Methotrexate; Initial disease status: Progressive Disease; Days to treatment start: 116 days; Days to treatment end: 136 days; Treatment outcome: Progressive Disease; Reason treatment ended: Disease Progression; Timepoint category: Post Initial Treatment; Treatment effect indicator: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lenalidomide + Romidepsin; Initial disease status: Progressive Disease; Days to treatment start: 140 days; Days to treatment end: 217 days; Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Clinical trial indicator: Yes; Timepoint category: Post Initial Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Stem Cell Transplantation, Allogeneic; Days to treatment start: 233 days; Treatment outcome: Complete Response; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease; Timepoint category: Postoperative.
   Recorded as not given: Organ Transplantation; adjuvant Radiation Therapy, NOS, postoperative; Stem Cell Transplantation, Allogeneic; Stem Cell Transplantation, Autologous; Stem Cell Transplantation, NOS.
2. Progression (histology not recorded by GDC). Age at diagnosis: 40.6 years (14,846 days); Days to diagnosis: 107 days.
3. Progression (histology not recorded by GDC). Age at diagnosis: 40.7 years (14,872 days); Days to diagnosis: 133 days.

Follow-up (5 entries)
- Day 107 (progression): Progression or recurrence: Yes; Days to progression: 107 days.
- Day 133 (progression): Progression or recurrence: Yes; Days to progression: 133 days.
- Days to follow up: 192 days; Disease response: Partial Response.
- Days to follow up: 266 days; Disease response: Tumor Free.
- Day 1,532 (end of treatment course 1): Disease response: Tumor Free; Imaging type: PET; Imaging result: Positive.

Molecular and laboratory tests
- Epstein-Barr Virus: Negative [Test analyte type: DNA].
- Lactate Dehydrogenase 1133 U/L [Blood test normal range upper: 250].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: GERD / Depression / Encephalitis / Neuropathy / Graft vs Host Disease.
- Timepoint category: Prior to Diagnosis; Risk factors: Skin Rash / Human Herpesvirus-6 (HHV-6) / BK Virus.
- Timepoint category: Initial Diagnosis; Weight: 74.2 kg; Height: 154 cm; BMI: 31.3.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample RC-B65M-NB1-A: Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen.
- Sample RC-B65M-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
